Gene-level copy-number profile of tumor specimen TCGA-VS-A8EC-01A from TCGA case TCGA-VS-A8EC, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 55.5 years (20,286 days).
Specimen TCGA-VS-A8EC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.bee1084d-680e-452b-8eb6-25b2235c570f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A8EC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1a198bae-5aeb-47ef-badd-0cb2f99252af

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 887; copy number 2: 6,201; copy number 3: 29,156; copy number 4: 12,906; copy number 5: 6,113; copy number 6: 1,170; copy number 7: 1,335; copy number 8: 686; copy number 9: 61; copy number 10: 203; copy number 12: 103; copy number 13: 553; copy number 14: 74; copy number 15: 152; copy number 16: 203; copy number 22: 6; copy number 23: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A8EC-01A-11D-A36I-01): tumor purity 0.86, ploidy 3.36, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,690,225–60,856,605, 4 genes: PPIAP70, AC104164.1, PPIAP71, U3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,379 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:62,939,916–64,593,005, 38 genes, copy number 9: RPS20P9, AC007098.1, OTX1, AC009501.1, AC009501.2, RPL27P5, DBIL5P2, WDPCP, Metazoa_SRP, MTFR2P1, AC016734.1, MDH1, PRELID1P6, RPS4XP5, RPL27P6, CSP1, HNRNPA1P66, UGP2, AC114748.1, VPS54, AC012368.2, PELI1, AC012368.1, LINC00309, AC012368.3, AC114752.1, AC114752.2, MIR4433B, MIR4433A, RPL23AP37, LGALSL-DT, AC008074.1, LGALSL, LINC01805, AC008074.2, AFTPH, MIR4434, RNU6-100P.
- chr2:66,820,684–67,825,562, 13 genes, copy number 7: DNMT3AP1, AC009474.1, LINC01799, LINC01628, AC007403.1, LINC01828, LINC01829, AC023115.1, ETAA1, LINC02831, AC007422.1, AC010987.1, LINC01812.
- chr2:84,290,683–87,196,629, 91 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr3:93,843,764–156,037,647, 1,056 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr3:157,174,201–157,381,265, 1 gene, copy number 7 (within-gene range 6–7): AC092944.1.
- chr3:157,259,742–198,222,513, 715 genes, copy number 7–22 (broad region; genes not listed).
- chr4:39,045,039–39,782,792, 25 genes, copy number 16 (within-gene range 2–16): KLHL5, AC079921.1, AC079921.2, WDR19, RFC1, RNU6-32P, RNU6-887P, KLB, MIR5591, Y_RNA, RPL9, LIAS, AC021148.1, UGDH, UGDH-AS1, AC021148.2, SMIM14, AC108471.3, RNU7-11P, AC108471.2, UBE2K, Y_RNA, AC108471.1, RN7SL558P, ZBTB12BP.
- chr4:51,843,000–62,220,470, 154 genes, copy number 16 (within-gene range 3–16) (broad region; genes not listed).
- chr6:134,169,246–134,950,115, 18 genes, copy number 7 (within-gene range 4–7): SGK1, RPS29P32, RNA5SP218, Y_RNA, AL355881.1, KRT8P42, LINC01010, Z84486.1, CHCHD2P4, CT69, AL078590.2, FAM8A6P, AL078590.1, AL596188.1, AL121970.1, MEMO1P2, ALDH8A1, AL445190.1.
- chr6:134,979,338–134,979,432, 1 gene, copy number 7: MIR3662.
- chr8:35,862,123–42,171,673, 138 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr14:72,853,224–106,875,071, 1,007 genes, copy number 10–15 (broad region; genes not listed).
- chr17:39,252,663–39,877,896, 21 genes, copy number 8 (within-gene range 5–8): FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2.
- chr21:25,639,258–25,717,562, 1 gene, copy number 16 (within-gene range 3–16): JAM2.
- chr21:25,692,180–27,143,949, 21 genes, copy number 16: FDX1P2, ATP5PF, GABPA, LLPHP2, APP, AP001442.1, RNU6-123P, AP001439.1, AP000229.1, RNU6-926P, AP001595.2, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1, ADAMTS1, AP001599.1, ADAMTS5, MIR4759, GPX1P2.
- chr21:27,361,121–27,395,787, 2 genes, copy number 16: AP001604.1, EIF4A1P1.
- chr21:34,353,099–37,661,496, 76 genes, copy number 14–23 (broad region; genes not listed).
- chr21:37,717,102–37,719,569, 1 gene, copy number 14: KCNJ6-AS1.

Autosomal genes at a single copy (total copy number 1): 887. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
